Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00F, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00F-01A (Primary Tumor).

1CD-0-3

Adenocarcinoma, NOS 8140/3

Site: sigmoid (per CQCF) C18.7 w 3/28/11

Sample ID #:

Diagnosis:

1.: Colon resectate under inclusion of a moderately differentiated adenocarcinoma of the colorectal type and of a max. size of 3 cm, with infiltration of the pericolic fatty tissue and seven regional lymph node metastases, one of which is located in the mesenteric resection margin. Tumor-free small and large intestinal resection margins.

2.: Ileocolon resectate under inclusion of a moderately differentiated adenocarcinoma of the colorectal type, formed at the base of a tubular adenoma with high-grade dysplasia and located in the cecum, with infiltration of the tunica submucosa. Tumor-free regional lymph nodes. Tumor-free small and large intestinal resection margins. Tumor-free mesenteric resection margin. Tumor-free appendix. Tumor-free omental fat tissue.

Tumor stage for 1.: pT3 pN2 (7/25) pMX; G2 L1 V0, locally R0

Tumor stage for 2.: pT1 pN0 (0/26) pMX; G2, L0, V0, R0

Diagnostic Discrepancy		

Source: NCI Genomic Data Commons file 43f6efcc-cb3b-4305-b04c-d8aaedaf7f7a (TCGA-AA-A00F.55E026EA-CC8D-4295-896D-0FFDACE323B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).